MMRF case MMRF_1310 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/590217ce-535c-483e-b866-4e383d075b41

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 80.1 years (29,239 days); ISS stage: II; Days to last known disease status: 1,534 days (4.2 years); Days to last follow up: 1,534 days (4.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 148 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 182 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 183 days; Days to treatment end: 211 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 225 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 0): M Protein 9.79 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.85 mg/dL; Immunoglobulin G 44 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 4.01 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 34 g/L; Total Protein 9.4 g/dL; Glucose 8.2 mmol/L; C-Reactive Protein 0.154 mg/dL.
- Day 86 (ECOG 0): M Protein 1.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.62 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 2.88 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 117 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.79 mmol/L.
- Day 166 (ECOG 1): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 8.28 g/L; Immunoglobulin A 0.77 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 8.97 mmol/L.
- Day 281 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.03 mg/dL; Immunoglobulin G 11.2 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.83 mmol/L.
- Day 370 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.82 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 11.6 g/L; Immunoglobulin A 1.71 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 3.69 µg/mL; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 6.55 mmol/L.
- Day 456 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.86 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 2.67 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 112 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.01 mmol/L.
- Day 547 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.08 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 3.91 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 8.62 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 7.4 g/dL; Glucose 5.5 mmol/L.
- Day 638: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 3.48 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 9.73 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 6.55 mmol/L.
- Day 722 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 3.08 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 9.49 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 7.2 g/dL; Glucose 4.24 mmol/L.
- Day 804 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.16 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 3.45 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.45 mmol/L.
- Day 888 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.43 mg/dL; Immunoglobulin G 15.2 g/L; Immunoglobulin A 3.67 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 74 ×10⁹/L; Creatinine 123 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.08 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 4.51 mmol/L.
- Day 986 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 3.33 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.99 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 5.83 mmol/L.
- Day 1,070 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 3.68 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 9.67 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 6.16 mmol/L.
- Day 1,154 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 3.19 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 5.23 mmol/L.
- Day 1,254 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.47 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 3.22 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 102 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 6.6 mmol/L.
- Day 1,338 (ECOG 1): Hemoglobin 9.8 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 121 ×10⁹/L.
- Day 1,422 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 12.6 g/L; Immunoglobulin A 3.15 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 9.3 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 138 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 5.83 mmol/L.
- Day 1,534 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.51 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 3.17 g/L; Immunoglobulin M 0.33 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 127 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 6.11 mmol/L.

Other clinical attributes
- Day -4: Weight: 80 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1310_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1310_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
